Somatic mutation profile of tumor specimen TCGA-28-1752-01A (aliquot TCGA-28-1752-01A-01W-0643-08) from TCGA case TCGA-28-1752, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 42.6 years (15,565 days).
Specimen TCGA-28-1752-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8825138e-a499-4d47-a31d-e9a9236b9ce8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-1752-10A (Blood Derived Normal), aliquot TCGA-28-1752-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a155b4a-5656-4626-b84b-3840d60bc08c

The open-access MAF lists 75 somatic variants for this specimen: 55 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 18, Nonsense Mutation 8, Frame Shift Ins 2, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 308/1723 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 20/325 reads (6%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 24/298 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2
- ADSS2 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as COSV100836779, COSV63694837; called by muse, mutect2
- ANOS1 | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99390271; called by muse, mutect2
- ARID4A | c.2353G>C p.E785Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV100793918, COSV100794476; called by muse, mutect2
- AURKB | c.628C>A p.L210I | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV100298538; called by muse, mutect2
- BEX4 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 22/209 reads (11%) | catalogued as rs1210792274, COSV101015316; called by muse, mutect2, varscan2
- C12orf54 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/628 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.187); catalogued as COSV100011467; called by muse, mutect2
- C1orf122 | c.268dup p.Q90Pfs*70 | Frame Shift Ins (INS) | VAF 10/75 reads (13%) | catalogued as rs747134922; called by mutect2, varscan2
- CASP1 | c.934G>T p.E312* (on ENST00000436863 / NM_033292.4; = p.E291* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/186 reads (4%) | catalogued as COSV62056899; called by muse, mutect2
- CENPI | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 13/144 reads (9%) | catalogued as COSV99514908, COSV99514930; called by muse, mutect2
- CHD1 | c.4195C>T p.P1399S | Missense Mutation (SNP) | VAF 18/245 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV99398940; called by muse, mutect2
- CNGA2 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.542); catalogued as rs138496370, COSV61706780; called by muse, mutect2, varscan2
- CNTN4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 75/717 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765118168, COSV100638650; called by muse, mutect2, varscan2
- COPB1 | c.826A>G p.T276A | Missense Mutation (SNP) | VAF 86/406 reads (21%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.458); catalogued as rs994019512, COSV99999144; called by muse, mutect2, varscan2
- CTAGE1 | c.1284dup p.A429Sfs*3 | Frame Shift Ins (INS) | VAF 14/77 reads (18%) | catalogued as rs756054046; called by mutect2, pindel, varscan2
- DLK1 | c.967G>C p.G323R | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV100374984; called by mutect2, varscan2
- EDEM2 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 122/520 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745432375, COSV100787981; called by muse, mutect2, varscan2
- EGFR | c.2320G>A p.V774M | Missense Mutation (SNP) | VAF 917/2622 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567477136, COSV51777313, COSV51843665; called by muse, mutect2, varscan2
- EML1 | c.216G>T p.Q72H | Missense Mutation (SNP) | VAF 8/234 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as COSV99214325; called by muse, mutect2
- EPHB6 | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1314287159, COSV63891467; called by muse, varscan2
- ESRP2 | c.886C>A p.R296S (on ENST00000565858 / NM_001365264.1; = p.R286S on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99251011; called by muse, mutect2, varscan2
- EXOSC10 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 17/520 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV58666323; called by muse, mutect2
- FAM135B | c.3905T>G p.L1302R | Missense Mutation (SNP) | VAF 107/466 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99417258; called by muse, mutect2, varscan2
- FARSA | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs764916782, COSV100108587; called by muse, mutect2, varscan2
- FDFT1 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 66/346 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594522; called by muse, mutect2, varscan2
- GLRA2 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54336257; called by muse, mutect2, varscan2
- ITIH5 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs768826767, COSV53662968; called by muse, mutect2, varscan2
- KHDC3L | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100950350; called by muse, varscan2
- KIF9 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 17/433 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV99646254; called by muse, mutect2
- KRT16 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 83/1000 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs762278898, COSV56967089; called by muse, mutect2
- KRT36 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs775869901, COSV100057288; called by muse, mutect2, varscan2
- MEIS3 | c.949C>T p.R317W (on ENST00000558555 / NM_001346148.1; = p.R363W on NM_020160.3) | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1246912582, COSV100520333; called by muse, mutect2
- MYO5B | c.5125G>A p.G1709S | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99543196; called by muse, mutect2, varscan2
- NAV2 | c.2417G>A p.W806* (on ENST00000396087 / NM_001244963.2; = p.W783* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 16/170 reads (9%) | catalogued as COSV100584409; called by muse, mutect2
- OAS2 | c.1619A>G p.K540R | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100659992; called by muse, mutect2
- OPHN1 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs200659608, COSV100830168; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR52E4 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 17/504 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); catalogued as COSV100389102; called by muse, mutect2
- OSTM1 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.247); catalogued as COSV99513902; called by muse, mutect2, varscan2
- PBXIP1 | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 62/231 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as COSV100869980, COSV63777843; called by muse, mutect2, varscan2
- PIF1 | c.1052C>T p.T351I | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV99164697; called by muse, mutect2
- POLR2G | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 21/518 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100080003; called by muse, mutect2
- PTPN3 | c.2632C>T p.R878* | Nonsense Mutation (SNP) | VAF 29/512 reads (6%) | catalogued as rs201209437, COSV52702199; called by muse, mutect2
- RB1 | c.2136C>A p.C712* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV99922632; called by muse, mutect2, varscan2
- RP1 | c.4000G>A p.V1334I | Missense Mutation (SNP) | VAF 42/236 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568312011, COSV99605788; called by muse, mutect2, varscan2
- RTF2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs762270957, COSV99196441; called by muse, mutect2, varscan2
- SCARA5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs757787499, COSV100107557, COSV100108037; called by muse, mutect2, varscan2
- ST18 | c.2380C>T p.R794C | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771688840, COSV52496353; called by muse, mutect2, varscan2
- STPG1 | c.29G>A p.R10H (on ENST00000337248 / NM_001199013.2; = p.A3T on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs1245180295, COSV50219597; called by muse, mutect2, varscan2
- TBR1 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV67419389; called by muse, mutect2, varscan2
- ZNF540 | c.60G>A p.W20* | Nonsense Mutation (SNP) | VAF 49/438 reads (11%) | catalogued as COSV100143435; called by muse, mutect2, varscan2
- ZNF81 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV100095239; called by muse, mutect2
- ZNF816-ZNF321P | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 65/379 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100008324; called by muse, mutect2, varscan2
- MDM1 | c.767A>G p.N256S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CEP63 | c.999C>A p.L333= | Silent (SNP) | VAF 51/576 reads (9%) | catalogued as COSV100132485; called by muse, mutect2
- KHDRBS2 | c.351G>A p.R117= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV55493864; called by muse, mutect2
- MRGPRX4 | c.660C>T p.L220= | Silent (SNP) | VAF 62/177 reads (35%) | catalogued as COSV100049608; called by muse, mutect2, varscan2
- MYH11 | c.1527C>T p.I509= | Silent (SNP) | VAF 58/271 reads (21%) | catalogued as rs564612796, COSV55571345, COSV55571944; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH2 | c.972C>T p.A324= | Silent (SNP) | VAF 37/274 reads (14%) | catalogued as COSV99819014; called by muse, mutect2, varscan2
- OBI1 | c.2148C>A p.S716= | Silent (SNP) | VAF 13/291 reads (4%) | catalogued as COSV56144263, COSV99932171; called by muse, mutect2
- OR4K15 | c.282C>T p.D94= (on ENST00000305051; = p.D70= on NM_001005486.1) | Silent (SNP) | VAF 31/397 reads (8%) | catalogued as rs774065100, COSV59300427; called by muse, mutect2
- OR7C2 | c.672C>T p.S224= | Silent (SNP) | VAF 28/257 reads (11%) | catalogued as rs765439544, COSV50180635; called by muse, mutect2, varscan2
- OR7D4 | c.498G>A p.L166= | Silent (SNP) | VAF 28/193 reads (15%) | catalogued as COSV100432550; called by muse, mutect2, varscan2
- PDHA2 | c.333C>T p.H111= | Silent (SNP) | VAF 47/346 reads (14%) | catalogued as rs375563184; called by muse, mutect2, varscan2
- RBM14 | c.1050C>T p.A350= | Silent (SNP) | VAF 89/357 reads (25%) | catalogued as COSV100036480; called by muse, mutect2, varscan2
- RHOXF2 | c.378G>A p.G126= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101002748; called by mutect2, varscan2
- SLC25A51 | c.339C>A p.V113= | Silent (SNP) | VAF 42/404 reads (10%) | catalogued as COSV99643230; called by muse, mutect2, varscan2
- SPATA31E1 | c.1569C>T p.T523= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100349712; called by muse, mutect2, varscan2
- TEX13B | c.138G>A p.V46= | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as COSV100258220; called by muse, mutect2, varscan2
- TEX15 | c.648G>A p.T216= (on ENST00000256246; = p.T599= on NM_001350162.2) | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs767912339, COSV56344847; called by muse, mutect2, varscan2
- USH2A | c.11445T>C p.S3815= | Silent (SNP) | VAF 26/226 reads (12%) | catalogued as COSV100227619; called by muse, mutect2, varscan2
- WIPF1 | c.1374G>A p.P458= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as rs757711719, COSV55812293; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.807C>T | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- OR2W5 | n.505C>A | RNA (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
